Surgical pathology report (de-identified scan), TCGA case TCGA-XF-A9T8, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site University of Southern California, specimen TCGA-XF-A9T8-01A (Primary Tumor).

[page 1 of 4]
Collected
Ordered by

Location

DIAGNOSIS:

RADICAL CYSTECTOMY WITH URINARY DIVISION (ILEAL CONDUIT) AND PELVIC LYMPH NODE
DISSECTION :

RIGHT URETER (AFS):

FROZEN SECTION DIAGNOSIS:

- NO TUMOR IDENTIFIED

FINAL DIAGNOSIS:

- BENIGN URETER

- NO DYSPLASIA OR MALIGNANCY IDENTIFIED

LEFT URETER (BFS):

FROZEN SECTION DIAGNOSIS:

- NO TUMOR IDENTIFIED

FINAL DIAGNOSIS:

- BENIGN URETER

- NO DYSPLASIA OR MALIGNANCY IDENTIFIED

BLADDER (C):

- INVASIVE POORLY DIFFERENTIATED UROTHELIAL CARCINOMA WITH SQUAMOID FEATURES (12.0 X 9.5 X 3.2 CM), GRADE 3-4/4, GROSSLY AND MICROSCOPICALLY EXTENDING THROUGH BLADDER WALL INTO PERIVESICLE SOFT TISSUE WITH IMPINGEMENT OF RIGHT DISTAL URETER AND RIGHT ANTERIOR PROXIMAL PROSTATE
- EXTENSIVE UROTHELIAL CARCINOMA IN SITU (FLAT LESION) THROUGHOUT BLADDER
- LYMPHOVASCULAR SPACE INVASION IDENTIFIED
- UNINVOLVED BLADDER SHOWS SQUAMOUS METAPLASIA AND EDEMATOUS CHANGE
- URETHRAL, URETERAL AND PERIVESICLE SOFT TISSUE RESECTION MARGINS, FREE OF DYSPLASIA AND MALIGNANCY

PROSTATE (C):

- BILATERAL PROSTATIC ADENOCARCINOMA, GLEASON'S SCORE 6 (3+3), CONFINED TO PROSTATE WITHOUT TRANSGRESSION OF CAPSULE
- BILATERAL SEMINAL VESICLES, FREE OF PROSTATIC AND UROTHELIAL CARCINOMA
- UNINVOLVED PROSTATE SHOWS GLANDULAR HYPERPLASIA
- APICAL AND RADIAL RESECTION MARGINS, FREE OF DYSPLASIA AND MALIGNANCY

LEFT EXTERNAL ILIAC LYMPH NODES (D):

- NO MALIGNANCY IDENTIFIED IN THREE LYMPH NODES EXAMINED (0/3)

LEFT LYMPH NODE OF CLOQUET (E):

- NO MALIGNANCY IDENTIFIED IN ONE LYMPH NODE EXAMINED (0/1)

LEFT OBTURATOR/HYPOGASTRIC LYMPH NODE (F):

- NO MALIGNANCY IDENTIFIED IN SEVEN LYMPH NODES EXAMINED (0/7)

RIGHT LYMPH NODE OF CLOQUET (G):

- NO MALIGNANCY IDENTIFIED IN ONE LYMPH NODE EXAMINED (0/1)

RIGHT EXTERNAL ILIAC LYMPH NODE (H):

- NO MALIGNANCY IDENTIFIED IN ONE LYMPH NODE EXAMINED (0/1)

RIGHT OBTURATOR/HYPOGASTRIC LYMPH NODE (I):

- NO MALIGNANCY IDENTIFIED IN FOUR LYMPH NODES EXAMINED (0/4)

LEFT PROXIMAL URETER (J):

- BENIGN URETER

- NO DYSPLASIA OR MALIGNANCY IDENTIFIED

*ICD O-3
Carcinoma, urothelial NOS 8120/3
Site: Bladder NOS C67.9
Bladder wall NOS C67.9
JDS 3/26/14*

Per TSS, 10% squamous.

[page 2 of 4]
Collected
Entered

Location

RIGHT PROXIMAL URETER (K):

- BENIGN URETER
- NO DYSPLASIA OR MALIGNANCY IDENTIFIED

LYMPH NODE SUMMARY: NO MALIGNANCY IDENTIFIED IN A TOTAL OF 17 LYMPH NODES EXAMINED (0/17).

PATHOLOGIC STAGING (AJCC 1997):

BLADDER: pT3bNOMX

PROSTATE: pT2bNOMX

SPECIMEN SOURCE:

AFS: "Right ureter"

BFS: "Left ureter"

C: "Prostate + bladder"

D: "Left external iliac LN"

E: "Left LN of cloquet"

F: "Left obturator/hypogastric LN"

G: "Right LN of cloquet"

H: "Right external iliac LN"

I: "Right obturator/hypogastric LN"

J: "Left proximal ureter"

K: "Rt proximal ureter"

CLINICAL INFORMATION:

Pre-Op Dx: Bladder carcinoma

Post-Op Dx: Same

GROSS EXAMINATION:

A: The specimen is received fresh from the O.R. and labeled "Right ureter". It consists of a 0.3 cm length of ureter measuring 0.4 cm in diameter. The outer surface is inked black and the specimen is entirely submitted in cassette AFS, following frozen section.

B: The specimen is received fresh from the O.R. and labeled "Left ureter". It consists of a 0.3 cm length of ureter measuring 0.4 cm in diameter. Entirely submitted in cassette BFS, following frozen section.

C: The specimen is received fresh from the O.R. and labeled "Prostate + bladder". It consists of a 590-gram cystoprostatectomy specimen consisting of bladder (10 x 6.5 x 3.2 cm), attached peritoneum (14 x 10 x < 0.1 cm), attached right ureter (4 x 0.4 cm), attached left ureter (4.5 x 0.4 cm), prostate (4 x 4 x 3.5 cm), right seminal vesicle (2.5 x 1.3 x 0.8 cm) and left seminal vesicle (2.5 x 1 x 0.6 cm). Opening the prostate and bladder anteriorly reveals a ulcerated and centrally necrotic tan-white tumor (12 x 9.5 x 3.2 cm) involving the entire right half of the bladder wall and extending to the dome, posterior wall, and inferiorly to the right anterior proximal prostate. Tumor diffusely replaces the bladder wall and extends into the perivesical fat with thickness of 3.2 cm. Tumor comes within 1 mm of the inked right resection margin. The mucosa beyond the central ulceration is granular and the uninvolved left lateral wall mucosa is edematous and smooth. The right ureter is impinged upon by tumor for a length of 2 cm from the ureterovesical junction. The mucosa of the bilateral ureters is otherwise unremarkable. The

[page 3 of 4]
Collected
Ordered by

Location

tumor causes a large area of retraction at the peritoneal surface but does not grossly transgress the peritoneum. The prostatic urethra measures 3.5 x 1.3 cm and the verumontanum measures 0.6 x 0.4 x 0.3 cm. The urethral mucosa is unremarkable.

Serial sectioning through the prostate reveals bilateral periurethral tan-white nodularities. Tumor is again noted extending to the right anterior proximal prostate. The seminal vesicles are uninvolved by tumor. Representative sections are submitted in 20 cassettes.

D: The specimen is received in formalin and labeled "Left external iliac LN". It consists of a 5 x 3.5 x 1 cm aggregate of tan-yellow fat and soft tissue. Three lymph nodes are identified ranging in size from 1 cm to 2.3 cm. Entirely submitted in three cassettes.

E: The specimen is received in formalin and labeled "Left LN of cloquet". It consists of a 0.7 x 0.6 x 0.3 cm tan-white apparent lymph node. Entirely submitted in one cassette.

F: The specimen is received in formalin and labeled "Left obturator/hypogastric LN". It consists of a 3.5 x 2.5 x 1 cm aggregate of tan-yellow fat and soft tissue. Multiple lymph nodes are identified ranging in size from 0.2 cm to 0.7 cm. Entirely submitted in three cassettes.

G: The specimen is received in formalin and labeled "Right LN of cloquet". It consists of a 0.8 x 0.8 x 0.6 cm lymph node which is bisected and entirely submitted in one cassette.

H: The specimen is received in formalin and labeled "Right external iliac LN". It consists of a 2.5 x 1.5 x 0.6 cm aggregate of tan-yellow fat and soft tissue. A single 1.2 cm lymph node is identified. The lymph node is bisected and submitted in cassette H1. The remaining tissue is submitted in cassette H2..

I: The specimen is received in formalin and labeled "Right obturator/hypogastric LN". It consists of a 3 x 2.5 x 1 cm aggregate of tan-yellow fat and soft tissue. Multiple lymph nodes are identified ranging in size from 0.3 cm to 2.5 cm. The largest lymph node is bisected and submitted in cassettes I1 and I2. The remaining tissue is submitted in cassette I3.

J: The specimen is received in formalin and labeled "Left proximal ureter". It consists of a 1.5 cm length of ureter measuring 0.5 cm in diameter. Serially sectioned and entirely submitted in one cassette.

K: The specimen is received in formalin and labeled "Rt proximal ureter". It consists of a 0.8 cm length of ureter measuring 0.5 cm in diameter. Serially sectioned and entirely submitted in one cassette.

SECTIONS:

AFS: frozen section, right ureter
BFS: frozen section, left ureter
C1: prostate + bladder, right lateral bladder wall and tumor
C2,3: tumor with closest right surgical resection margin
C4: right ureterovesical junction
C5: anterior wall and tumor
C6: dome and tumor
C7: posterior wall and tumor
C8: left lateral wall
C9: left ureterovesical junction
C10: bladder neck/trigone
C11: right perivesical fat and possible lymph nodes
C12: left perivesical fat
C13: right posterior proximal prostate

[page 4 of 4]
Collected:
Ordered by:

Location:

C14: right anterior proximal prostate
C15: left proximal prostate
C16: right mid prostate
C17: left mid prostate
C18: right distal prostate
C19: left distal prostate
C20: apical margin
D1: left external iliac lymph node; one bisected lymph node
D2: one bisected lymph node
D3: remaining lymph node and soft tissue
E: left lymph node of Cloquet - all embedded
F1-3: left obturator/hypogastric lymph node - all embedded
G: right lymph node of Cloquet - all embedded
H1: right external iliac lymph node; one lymph node, bisected
H2: remaining tissue
I1,2: right obturator/hypogastric lymph node; largest lymph node
I3: remaining tissue
J: left proximal ureter - all embedded
K: right proximal ureter - all embedded

INTRAOPERATIVE FROZEN CONSULTATION:

AFS: Right ureter:
- no tumor identified

BFS: Left ureter:
- no tumor identified

Source: NCI Genomic Data Commons file 413d5381-c94d-41ec-a2a9-89db90956b68 (TCGA-XF-A9T8.7F4BAF33-CF00-4B19-914A-5AA8CFB3D797.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).